Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9O9, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9O9-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Bladder neck, margin, biopsy: Benign fibromuscular tissue and benign glands with extensive cautery artifact.
- B. Lymph nodes, right pelvis, biopsy: No tumor identified in eight lymph nodes (0/8).
- C. Prostate, seminal vesicles, and left-sided pelvic lymph nodes, total prostatectomy and lymph node dissection:
1. Prostatic carcinoma, bilateral, Gleason grade 3+5=8; see comment.
2. No tumor identified in four lymph nodes (0/4).

COMMENT:

Synoptic Comment for Prostate Tumors

1. Type of tumor: Small acinar adenocarcinoma.
2. Location of tumor: Left apex, slide C2; left posterior apex, slide C10; left posterior mid gland, slide C12; left anterior mid gland, slide C15; right apex, slide C1; right posterior apex, slide C6; right posterior mid gland, slides C7, C8; right posterior base, slides C9, C19; right anterior mid gland, slide C5.
3. Estimated volume of tumor: 0.96 cm, cubed (largest tumor nodule present in slide C7, 0.42 cm, cubed; slide C8, 0.54 cm, cubed).
4. Gleason score: 3+5; primary pattern 3, secondary pattern 5.
5. Estimated volume > Gleason pattern 3 (includes both patterns 4 and 5 added together): 20%.
6. Involvement of capsule: Tumor invades capsule (slides C5-C9, C12, C15).
7. Extraprostatic extension: Present, extensive.
8. Status of excision margins for tumor: No tumor at inked excision margins.
Status of excision margins for benign prostate glands: No benign glands present at inked excision margins.
9. Involvement of seminal vesicle: Present, right side.
10. Perineural infiltration: Present.
11. Prostatic intraepithelial neoplasia (PIN): Not identified.
12. AJCC/UICC stage: pT3bN0MX.

ICD: O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 61.9
7/23/27/14

[page 2 of 3]
The possibility of lymphovascular invasion was evaluated by performing and examining an immunoperoxidase stain for D2-40 on block C19. No LVI was identified.

Specimen(s) Received

A: Bladder neck margin

B: Right pelvic lymph nodes

C: Prostate, seminal vesicles and left side pelvic lymph nodes (fresh)

Clinical History

The patient is a [REDACTED] with a history of prostate cancer, by core biopsy, Gleason grade ranging from 3+3 (6) to 4+5 (9). The patient undergoes robot-assisted laparoscopic radical prostatectomy with bilateral pelvic lymph node dissections.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and unit number. Parts A and B are received in formalin and Part C is received fresh.

Part A, additionally labeled "bladder neck margin," consists of three irregular, tan-brown, heavily cauterized, unoriented tissue fragments measuring 1.8 x 1.5 x 0.5 cm in aggregate. The specimen is entirely submitted in cassette A1.

Part B, additionally labeled "right pelvic lymph nodes," consists of a single irregular fragment of yellow-tan fibrofatty tissue measuring 3.7 x 2.5 x 0.8 cm. Multiple lymph node candidates are identified and submitted as follows:

Cassettes B1-B2: One lymph node candidate.

Cassette B3: One lymph node candidate, bisected.

Cassette B4: Multiple small lymph node candidates, submitted intact.

Part C, labeled "prostate, seminal vesicles and left pelvic lymph nodes," consists of a single large intact prostate gland with attached seminal vesicle/vas deferens bundles weighing 72.5 gm. The specimen measures 5.1 cm from apex to base, 5 cm from medial to lateral, and 4.4 cm from anterior to posterior. The external surface of the gland is roughened, red-tan, and glistening, with an additional fibrofatty margin taken along the right lateral posterior aspect. There is a line of small silver-gray laparoscopic staples closing the anterior midline. The base/bladder margin demonstrates extensive cautery markings. The seminal vesicle/vas deferens bundles appear soft, red-tan, whorled, and unremarkable. The right anterior surface of the gland is inked in green, the left anterior surface is inked in blue, and the posterior surface is inked in black. The specimen is bisected perpendicular to the urethral channel through the mid gland. 3 mm core biopsies are taken from a large tumor mass in the right lower quadrant of the mid-base region. Also slices are taken of the right posterior and mid-central quadrants.

The two halves are then glued, and the specimen is fixed prior to further sectioning. Following formalin fixation, the bladder margin is removed, and the remainder of the gland is serially sectioned from apex to base, perpendicular to the urethral channel, into eight serial slices. Serial slice 9 extends beyond the true prostatic/seminal vesicle junction, which is noted in serial slice 8. Serial slice 9 is composed almost entirely of firm, striated, white-tan tissue. The remaining serial slices demonstrate an enlarged central/transitional zone composed of nodular and firm, white-tan, striated tissue. A single dominant nodule is noted in the right posterior quadrant, noted in the apical margin through serial slice 8. This lesion is composed of solid white-tan tissue measuring 1.5 cm in greatest dimension. The lesion grossly abuts the prostatic capsule in the posterior lateral aspect of the right posterior quadrant. The remaining peripheral zone is unremarkable and is composed of soft, semi-porous, light tan tissue throughout. Additionally submitted within the same container is a single irregular segment of soft to firm, yellow-tan, fibrofatty tissue measuring 5.5 x 3.5 x 1 cm in greatest dimension. Multiple lymph node candidates are identified. The apical and bladder margins, as well as representative sections of the prostate, seminal vesicles and lymph node candidates, are submitted as follows:

Apical margins

Cassette C1: Right apex, 12 - 6 o'clock, bread-loafed and entirely submitted.

Cassette C2: Left apex, 6 - 12 o'clock, bread-loafed and entirely submitted.

[page 3 of 3]
Right anterior quadrant

Cassette C3: Serial slice 2.

Cassette C4: Serial slice 4.

Cassette C5: Serial slice 6.

Right posterior quadrant

Cassette C6: Serial slice 2.

Cassette C7: Serial slice 4.

Cassette C8: Serial slice 6.

Cassette C9: Serial slice 8, right posterior margin, bread-loafed.

Left posterior quadrant

Cassette C10: Serial slice 2.

Cassette C11: Serial slice 4.

Cassette C12: Serial slice 6.

Left anterior quadrant

Cassette C13: Serial slice 2.

Cassette C14: Serial slice 4.

Cassette C15: Serial slice 6.

Bladder margins

Cassette C16: Right lateral bladder margin, bread-loafed and entirely submitted.

Cassette C17: Central bladder margin.

Cassette C18: Left lateral bladder margins, bread-loafed and entirely submitted.

Prostatic/Seminal vesicle junction

Cassette C19: Right seminal vesicle and cross-section of vas deferens.

Cassette C20: Left seminal vesicle and cross-section of vas deferens.

Lymph nodes

Cassettes C21-C22: One lymph node candidate, multiply sectioned.

Cassettes C23-C24: One lymph node candidate, multiply sectioned.

Cassette C25: Two small lymph node candidates, bisected.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by th-

They have not been cleared or approved by

The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file 7098d639-a043-4202-b48a-36e765b9a186 (TCGA-V1-A9O9.6AEA4F7C-2680-4BCE-BB38-AF8DF5ED7DE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).